TCGA case TCGA-13-1412 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/44493c23-82e9-4d9f-8e3c-7b3f9ae44970

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Dead; Days to death: 984 days (2.7 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 41.4 years (15,119 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 121 days; Number of cycles: 5; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 121 days; Number of cycles: 5; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 156 days; Days to treatment end: 205 days; Number of cycles: 3; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 156 days; Days to treatment end: 205 days; Number of cycles: 3; Prescribed dose: 135; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 156 days; Days to treatment end: 205 days; Number of cycles: 3; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intraperitoneal.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.5 years (15,528 days); Days to diagnosis: 409 days (1.1 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 162 days; Disease response: Tumor Free.
- Day 409 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 984 days (2.7 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-1412-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-13-1412-01A-01-BS1: Section location: Bottom; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
  Slide TCGA-13-1412-01A-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
- Sample TCGA-13-1412-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4, Route of administrations: Route of administration: IP.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy.
- Follow-up form 2: Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 984 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 984 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 409 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-1412-01A-01D-0452-01): tumor purity 0.69, ploidy 2.06, whole-genome doublings 0.
